Surgical pathology report (de-identified scan), TCGA case TCGA-22-5472, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5472-01A (Primary Tumor).

DIAGNOSIS:

Lung, right middle lobe, wedge biopsy: Subpleural fibrosis and focal osseous metaplasia.

Lung, right lower lobe, lobectomy: Invasive grade 3 (of 4) non-keratinizing squamous cell carcinoma forming a 3.8 x 3.0 x 1.8 cm subpleural mass that involves the visceral pleura. The margins of resection are negative for tumor. The surrounding lung parenchyma shows septal and subpleural fibrosis, focal honeycomb change, and areas of organizing pneumonia (see comment).

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (4) right lower paratracheal (station 4R) lymph nodes.
- No tumor is identified in multiple (3) subcarinal (station 7) lymph nodes.

Lymph nodes, hilar/intrapulmonary, excision:

- No tumor is identified in multiple (8) intrapulmonary peribronchial lymph nodes.

Source: NCI Genomic Data Commons file 2a6f2dfb-09b4-4aaf-a45d-6bd42c32b5e8 (TCGA-22-5472.A882EB26-0B08-463E-9700-4396FCE9E8FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).